Gene-level copy-number profile of tumor specimen TCGA-D7-6822-01A from TCGA case TCGA-D7-6822, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 77.2 years (28,214 days).
Specimen TCGA-D7-6822-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.783b05a2-16f8-4a7f-8a79-87919e7bda3b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6822-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8ca91396-e727-4bfc-ae1d-61e6f09432c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 9,017; copy number 2: 32,582; copy number 3: 8,925; copy number 4: 8,853; copy number 5: 101; copy number 6: 263; copy number 7: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6822-01A-11D-1881-01): tumor purity 0.73, ploidy 2.32, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:61,561,569–62,297,609, 3 genes (within-gene range 0–1): PTPRG, Y_RNA, RPL10AP6.
- chr3:71,289,769–71,305,853, 1 gene: FOXP1-AS1.
- chr4:41,084,607–41,114,045, 2 genes: RNU6-836P, RNU6-1195P.
- chr4:170,581,470–171,638,763, 13 genes (within-gene range 0–1): HSP90AA6P, LINC02382, AC097486.1, RNU6ATAC13P, AC034159.2, LINC02431, AC034159.1, AC092639.1, MIR6082, LINC02504, AC074254.2, LINC02174, AC074254.1.
- chr4:186,587,794–186,726,722, 2 genes (within-gene range 0–1): FAT1, AC107050.1.
- chr5:59,314,110–59,314,800, 1 gene: AC008833.1.
- chr5:59,703,606–60,033,020, 2 genes (within-gene range 0–1): MIR582, AC034234.1.
- chr7:109,998,434–110,534,757, 3 genes (within-gene range 0–1): RPL3P8, AC073114.1, AC073114.2.
- chr17:1,344,275–1,400,222, 2 genes: YWHAE, AC032044.2.
- chr17:11,598,470–12,215,267, 10 genes (within-gene range 0–1): DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2.
- chr18:10,454,635–10,489,949, 1 gene (within-gene range 0–1): APCDD1.
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 375 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,782,671–152,644,717, 157 genes, copy number 6 (broad region; genes not listed).
- chr1:181,771,566–184,629,019, 63 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:206,865,354–207,099,993, 11 genes, copy number 6: IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB.
- chr1:234,811,052–234,980,804, 6 genes, copy number 6: AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr6:101,181,257–102,070,083, 1 gene, copy number 5 (within-gene range 2–5): GRIK2.
- chr6:102,078,872–102,079,555, 1 gene, copy number 5: AP002530.1.
- chr9:101,322,477–101,482,199, 11 genes, copy number 7 (within-gene range 3–7): AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1.
- chr10:1,361,001–1,556,984, 2 genes, copy number 6 (within-gene range 2–6): AL513304.1, ADARB2-AS1.
- chr13:73,112,915–73,227,260, 3 genes, copy number 5: RNU6-66P, RNU4-10P, RNY1P8.
- chr17:21,678,086–22,706,703, 33 genes, copy number 5: AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr20:20,970,448–23,988,779, 87 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,522. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
